Somatic mutation profile of tumor specimen ALCH-B3JN-TTP1-A (aliquot ALCH-B3JN-TTP1-A-2-0-D-A80D-36) from ALCHEMIST case ALCH-B3JN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 80.4 years (29,352 days).
Specimen ALCH-B3JN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6325893b-bf4a-4456-83d9-ddf8b8f30c67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3JN-NB1-A (Blood Derived Normal), aliquot ALCH-B3JN-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b5e4ac3-7392-4aef-903b-a99953d19ec6

The open-access MAF lists 265 somatic variants for this specimen: 181 protein-altering or splice-affecting, 60 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 153, Silent 60, Nonsense Mutation 13, Intron 7, Splice Site 6, 5'Flank 5, 3'UTR 5, RNA 4, Frame Shift Del 4, Translation Start Site 2, 3'Flank 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC12A1 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs896545456, CM077226, COSV57708019; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 23/137 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2M | c.1699A>G p.K567E | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs376425831; called by muse, mutect2, varscan2
- AKR1B15 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV71152712; called by muse, mutect2, varscan2
- ANAPC1 | c.3724G>A p.E1242K | Missense Mutation (SNP) | VAF 38/361 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs937632916; called by muse, mutect2, varscan2
- ANKDD1B | c.648A>C p.E216D | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.617); catalogued as rs1299316556; called by muse, mutect2, varscan2
- ASH1L | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 42/270 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV64214014; called by muse, mutect2, varscan2
- BCOR | c.2560G>A p.A854T | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.001); catalogued as rs527732438, COSV60707971; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BEND2 | c.1098G>T p.Q366H | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as COSV66216491; called by muse, mutect2, varscan2
- C6 | c.1578C>A p.C526* | Nonsense Mutation (SNP) | VAF 25/245 reads (10%) | catalogued as COSV54710829; called by muse, mutect2, varscan2
- CD1C | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.094); catalogued as COSV63806443; called by muse, mutect2, varscan2
- COL6A1 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs886057155; ClinVar: uncertain significance; called by muse, mutect2
- CPED1 | c.2641T>A p.L881I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59996960; called by muse, mutect2
- DBT | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs955737855; called by muse, mutect2, varscan2
- DDX53 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as rs1569253298, COSV60069515; called by muse, mutect2, varscan2
- EPPK1 | c.1545C>G p.F515L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV101599986, COSV73261523; called by muse, mutect2, varscan2
- FAM135A | c.217C>T p.Q73* (on ENST00000370479 / NM_001351599.1; = p.Q30* on NM_020819.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/140 reads (17%) | catalogued as COSV99524987; called by muse, mutect2, varscan2
- FARP2 | c.2627C>T p.S876F | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.751); catalogued as rs1194381303, COSV50884245; called by muse, varscan2
- FAT1 | c.9536G>A p.G3179E | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1232866727, COSV71674338; called by muse, mutect2, varscan2
- FAT1 | c.5854G>C p.V1952L | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV71675788; called by muse, mutect2, varscan2
- FEM1C | c.1685_1688del p.Q562Lfs*11 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | catalogued as rs1276129164; called by pindel, varscan2
- FILIP1L | c.2598G>A p.M866I (on ENST00000354552 / NM_182909.3; = p.M626I on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV58771875; called by muse, mutect2, varscan2
- GABRG2 | c.21G>A p.W7* | Nonsense Mutation (SNP) | VAF 43/418 reads (10%) | catalogued as COSV62722838; called by muse, mutect2
- GDF9 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422934319, COSV51526934; called by muse, mutect2, varscan2
- GTF3C2 | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs769518542, COSV51990097; called by muse, mutect2, varscan2
- H2AC16 | c.248A>G p.H83R | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as rs190008233; called by muse, mutect2, varscan2
- HEPH | c.3080G>T p.G1027V (on ENST00000343002; = p.G760V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57960003, COSV57972321; called by muse, mutect2, varscan2
- HERC1 | c.4903G>A p.E1635K | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV101496567; called by muse, mutect2
- HIGD2B | c.140C>A p.P47Q | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100304529; called by muse, mutect2, varscan2
- IKBKB | c.757G>T p.V253L | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs140074007; called by muse, mutect2, varscan2
- ITPRID1 | c.1879C>A p.P627T | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as COSV60075775; called by muse, mutect2, varscan2
- KCNB1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as COSV100870604; called by muse, mutect2
- KMT2C | c.13132G>T p.E4378* | Nonsense Mutation (SNP) | VAF 24/130 reads (18%) | catalogued as COSV51498798; called by muse, mutect2, varscan2
- LDB2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773610304, COSV58764089; called by muse, mutect2, varscan2
- MRPL3 | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.895); catalogued as rs775175471, COSV99078017; called by muse, mutect2, varscan2
- MRPS28 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52562069, COSV52563206; called by muse, mutect2, varscan2
- MRRF | c.65C>G p.S22C | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.174); catalogued as COSV52916168; called by muse, mutect2, varscan2
- NCR2 | c.280G>T p.V94F | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66101204; called by muse, mutect2, varscan2
- NEDD4 | c.2810A>G p.Y937C (on ENST00000508342 / NM_001284338.1; = p.Y518C on NM_006154.4) | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746211690; called by muse, mutect2, varscan2
- NLGN3 | c.1325G>T p.G442V (on ENST00000358741 / NM_181303.2; = p.G422V on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100705126; called by muse, mutect2, varscan2
- NUP160 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1267625040; called by muse, mutect2, varscan2
- OPLAH | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as rs781883174; called by muse, mutect2, varscan2
- OR1C1 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101376274; called by muse, mutect2, varscan2
- OR4C15 | c.605G>T p.W202L (on ENST00000314644; = p.W148L on NM_001001920.2) | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.149); catalogued as COSV58952678, COSV58956015; called by muse, mutect2, varscan2
- OR5W2 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.086); catalogued as COSV60617195; called by muse, mutect2
- PABPC3 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.619); catalogued as rs372920602; called by muse, mutect2
- PAPPA2 | c.3827G>A p.R1276K | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs1413549229; called by muse, mutect2, varscan2
- PCDHA12 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.077); catalogued as COSV56534021; called by muse, mutect2, varscan2
- PIP5K1A | c.475G>A p.D159N (on ENST00000368888 / NM_001135638.2; = p.D146N on NM_003557.3) | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs753241257; called by muse, mutect2, varscan2
- PLXNA3 | c.4409G>A p.R1470H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63754154; called by muse, mutect2, varscan2
- PLXND1 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1462608717; called by muse, mutect2
- RB1 | c.2043G>A p.W681* | Nonsense Mutation (SNP) | VAF 101/349 reads (29%) | catalogued as COSV57304425, COSV57313978; called by muse, mutect2, varscan2
- SPACA7 | c.57G>A p.W19* | Nonsense Mutation (SNP) | VAF 19/129 reads (15%) | catalogued as rs765350858, COSV99366907; called by muse, mutect2, varscan2
- SPAG6 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 66/430 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as rs750952431, COSV57619084; called by muse, mutect2, varscan2
- STRIP2 | c.1649C>A p.P550H | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50806689, COSV50811315; called by muse, varscan2
- SYNE2 | c.13258A>G p.T4420A | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1455585667, COSV59965360; called by muse, mutect2, varscan2
- TCHH | c.2852G>A p.R951K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.046); catalogued as rs762558880; called by muse, varscan2
- TENM3 | c.1592G>A p.G531E | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69318726; called by muse, mutect2, varscan2
- TMEM132B | c.2209G>C p.V737L | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs756720340; called by muse, mutect2, varscan2
- TNFAIP3 | c.1239G>T p.K413N | Missense Mutation (SNP) | VAF 57/310 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV52802978, COSV52803535; called by muse, mutect2, varscan2
- TNXB | c.11500G>A p.V3834M (on ENST00000647633; = p.V3587M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.394); catalogued as rs560288296, COSV100925955; called by muse, mutect2
- TTLL9 | c.306del p.N103Tfs*5 | Frame Shift Del (DEL) | VAF 14/85 reads (16%) | catalogued as COSV60593279; called by mutect2, pindel, varscan2
- URB2 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763537395, COSV99270674; called by muse, mutect2, varscan2
- USH2A | c.1900G>C p.A634P | Missense Mutation (SNP) | VAF 123/424 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100245191; called by muse, mutect2, varscan2
- VPS13D | c.11330C>G p.S3777C | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs149521489, COSV50646383; called by muse, mutect2, varscan2
- VPS41 | c.1375C>T p.L459F | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV59648999; called by muse, mutect2, varscan2
- XIAP | c.302G>T p.S101I | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV63022239; called by muse, mutect2, varscan2
- ZNF430 | c.840G>T p.K280N | Missense Mutation (SNP) | VAF 25/254 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs879128159, COSV55108955; called by muse, mutect2
- ZNF629 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373186496; called by mutect2, varscan2
- ABCA2 | c.5117G>T p.G1706V (on ENST00000614293; = p.G1676V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACE2 | c.880A>T p.T294S | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ACSM3 | c.1582C>A p.P528T | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2
- ADAM9 | c.1534T>C p.C512R | Missense Mutation (SNP) | VAF 29/826 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AKAP13 | c.2331G>T p.Q777H | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ANKRD52 | c.1786G>T p.G596C | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP30 | c.2785G>A p.V929I (on ENST00000368013 / NM_001025598.2; = p.V718I on NM_181720.3) | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP10D | c.533G>C p.G178A | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATP11C | c.2797A>T p.I933F | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ATP6V0A2 | c.1352G>T p.R451L | Missense Mutation (SNP) | VAF 34/267 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BOD1L1 | c.8035G>C p.E2679Q | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CA3 | c.755A>G p.N252S | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNB1 | c.668A>T p.Y223F | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CAPN6 | c.1819G>T p.D607Y | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CCDC141 | c.3060+1G>T p.X1020_splice | Splice Site (SNP) | VAF 50/293 reads (17%) | called by muse, mutect2, varscan2
- CCDC17 | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC60 | c.1619A>T p.N540I | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- CDC42BPB | c.205A>T p.M69L | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPQ | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 33/268 reads (12%) | called by muse, mutect2, varscan2
- CNTRL | c.6001G>C p.E2001Q | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- CREB3L3 | c.1358G>T p.G453V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CTSC | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CYTH1 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- DCAF8L2 | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- DCDC1 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DNAH5 | c.12909+1G>A p.X4303_splice | Splice Site (SNP) | VAF 30/231 reads (13%) | called by muse, mutect2, varscan2
- DNAH6 | c.2644G>A p.V882I | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- DNAH7 | c.3838G>C p.E1280Q | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ECT2 | c.207A>T p.L69F | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2
- ERBB2 | c.1556A>G p.H519R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- EYS | c.1963G>T p.G655* | Nonsense Mutation (SNP) | VAF 74/471 reads (16%) | called by muse, varscan2
- F3 | c.571A>G p.K191E | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- FAT2 | c.9052G>T p.G3018C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FBN2 | c.7003G>A p.G2335S | Missense Mutation (SNP) | VAF 31/319 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- FOXI1 | c.415del p.A139Hfs*93 | Frame Shift Del (DEL) | VAF 48/254 reads (19%) | called by mutect2, pindel, varscan2
- FREM3 | c.4521G>C p.K1507N | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRMD7 | c.542C>A p.A181E | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FRMPD4 | c.3124G>A p.G1042R | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT5 | c.77T>G p.L26R | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- GIGYF2 | c.2428G>C p.E810Q | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GOLGA8A | c.1836G>T p.L612F (on ENST00000432566; = p.L584F on NM_181077.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/555 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPRC6A | c.2247A>G p.I749M | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.076); called by muse, mutect2
- GRIA1 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GTF2F1 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- H3C10 | c.195G>C p.K65N | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- HIVEP1 | c.669_670insG p.L224Afs*5 | Frame Shift Ins (INS) | VAF 12/101 reads (12%) | called by mutect2, varscan2
- HLX | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- HTR1A | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRGM | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- KAT6A | c.843T>A p.C281* | Nonsense Mutation (SNP) | VAF 35/253 reads (14%) | called by muse, mutect2, varscan2
- KIR2DL3 | c.128A>G p.E43G | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- KLHL32 | c.305C>G p.T102R | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LEPR | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- LRP2 | c.10572-1G>C p.X3524_splice | Splice Site (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- LY75 | c.2930G>A p.S977N | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LYST | c.7808C>G p.T2603S | Missense Mutation (SNP) | VAF 50/421 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAG | c.1537A>C p.K513Q | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- MILR1 | c.854A>T p.K285M | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.099); called by muse, varscan2
- MYH4 | c.5781G>T p.K1927N | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- MYH9 | c.2483G>A p.W828* | Nonsense Mutation (SNP) | VAF 24/184 reads (13%) | called by muse, mutect2, varscan2
- MYOCD | c.1349G>C p.G450A | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- NBAS | c.6218A>T p.H2073L | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.282); called by muse, mutect2
- NEDD1 | c.234A>G p.Q78= | Splice Region (SNP) | VAF 10/49 reads (20%) | called by muse, varscan2
- NEUROD4 | c.333_337dup p.V113Gfs*16 | Frame Shift Ins (INS) | VAF 16/114 reads (14%) | called by mutect2, varscan2
- NEUROD4 | c.851C>G p.P284R | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NR2E1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 51/349 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- NUMBL | c.1771G>C p.E591Q | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NXPE1 | c.1189C>A p.Q397K (on ENST00000424269; = p.Q255K on NM_152315.5) | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- OR4K13 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.38); called by muse, varscan2
- OR5T2 | c.985T>G p.Y329D | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- OR5T3 | c.845A>G p.H282R | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- OR6X1 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR8I2 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- P4HB | c.1190G>A p.C397Y | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PCLO | c.5287C>T p.H1763Y | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PDE6C | c.2050T>C p.F684L | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PHKA2 | c.2921A>T p.H974L | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PHKA2 | c.404T>G p.V135G | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- POU3F3 | c.1248C>A p.S416R | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- POU3F4 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 40/351 reads (11%) | called by muse, mutect2, varscan2
- PPIAL4A | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 40/635 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- PRKAG3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 19/118 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RFX6 | c.1327+1G>C p.X443_splice | Splice Site (SNP) | VAF 45/273 reads (16%) | called by muse, mutect2, varscan2
- RFX6 | c.1327+2T>A p.X443_splice | Splice Site (SNP) | VAF 38/271 reads (14%) | called by muse, mutect2, varscan2
- RNF213 | c.10685T>C p.V3562A | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPH3A | c.450del p.W150* (on ENST00000389385 / NM_001143854.2; = p.W146* on NM_014954.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel
- RPS6KA3 | c.301G>T p.V101L | Missense Mutation (SNP) | VAF 58/441 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- SCRT1 | c.621C>G p.S207R | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SDS | c.929T>A p.L310Q | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SERPINB9 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC13A3 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- SLC25A36 | c.530A>G p.Y177C | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC3A1 | c.1602C>A p.H534Q | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPINK5 | c.2608G>T p.V870F | Missense Mutation (SNP) | VAF 67/459 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- STMND1 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- STX7 | c.748G>C p.A250P | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYMPK | c.1018C>G p.P340A | Missense Mutation (SNP) | VAF 63/313 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- SYMPK | c.1017G>T p.M339I | Missense Mutation (SNP) | VAF 67/319 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TCHH | c.2836G>C p.E946Q | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); called by muse, varscan2
- THSD7A | c.4825T>A p.Y1609N | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMCO6 | c.229G>C p.G77R | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- TMEM168 | c.1751A>G p.Q584R | Missense Mutation (SNP) | VAF 65/360 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TOPORS | c.2642A>G p.H881R | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TSPAN7 | c.491A>G p.Y164C | Missense Mutation (SNP) | VAF 47/278 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- TTN | c.45224C>A p.T15075N (on ENST00000591111; = p.T7651N on NM_003319.4) | Missense Mutation (SNP) | VAF 31/268 reads (12%) | PolyPhen benign (0.015); called by muse, mutect2, varscan2
- UTRN | c.3520G>A p.D1174N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); called by muse, mutect2
- WDFY1 | c.334+2T>C p.X112_splice | Splice Site (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- ZBED6 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZBTB37 | c.444A>C p.R148S | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZBTB7A | c.1609C>T p.H537Y | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.185); called by muse, mutect2
- ZNF554 | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- ZNF808 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- ABHD10 | c.411A>T p.I137= | Silent (SNP) | VAF 82/231 reads (35%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.5049C>A p.G1683= | Silent (SNP) | VAF 56/184 reads (30%) | called by muse, mutect2, varscan2
- ANKRD11 | c.7581C>A p.I2527= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV99970339; called by muse, mutect2, varscan2
- C11orf16 | c.1083G>A p.V361= | Silent (SNP) | VAF 19/160 reads (12%) | called by muse, mutect2, varscan2
- CASKIN2 | c.645C>T p.I215= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs759445740; called by muse, mutect2, varscan2
- CDHR2 | c.309C>T p.Y103= | Silent (SNP) | VAF 16/76 reads (21%) | called by muse, mutect2
- CHRFAM7A | c.291C>T p.I97= | Silent (SNP) | VAF 30/364 reads (8%) | called by muse, mutect2
- CMYA5 | c.10045C>T p.L3349= | Silent (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- CTNNA1 | c.1989G>C p.L663= | Silent (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- DDC | c.261G>T p.P87= | Silent (SNP) | VAF 37/229 reads (16%) | catalogued as COSV63563685; called by muse, mutect2, varscan2
- DNAJC13 | c.1488G>A p.L496= | Silent (SNP) | VAF 21/205 reads (10%) | called by muse, mutect2
- EYS | c.7449C>G p.L2483= | Silent (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- GLIS2 | c.594G>A p.K198= | Silent (SNP) | VAF 21/124 reads (17%) | called by muse, mutect2, varscan2
- GMPR | c.663C>A p.G221= | Silent (SNP) | VAF 19/180 reads (11%) | catalogued as COSV52471955; called by muse, varscan2
- GNAS | c.177C>T p.I59= | Silent (SNP) | VAF 23/132 reads (17%) | catalogued as COSV58342515; called by muse, mutect2, varscan2
- GRIK5 | c.402G>T p.A134= | Silent (SNP) | VAF 39/150 reads (26%) | called by muse, mutect2, varscan2
- HEPH | c.3081G>T p.G1027= (on ENST00000343002; = p.G760= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/161 reads (14%) | called by muse, mutect2, varscan2
- HTR1A | c.816G>T p.G272= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- INTS2 | c.3147A>G p.P1049= | Silent (SNP) | VAF 21/165 reads (13%) | catalogued as rs372703637; called by muse, mutect2, varscan2
- IVL | c.1383G>A p.K461= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV100908061, COSV64216157; called by muse, mutect2
- KCNB2 | c.1536C>T p.Y512= | Silent (SNP) | VAF 23/182 reads (13%) | catalogued as COSV73049226; called by muse, mutect2, varscan2
- KCNG3 | c.792G>A p.P264= | Silent (SNP) | VAF 18/135 reads (13%) | catalogued as rs770589742; called by muse, mutect2, varscan2
- KISS1 | c.321G>A p.K107= | Silent (SNP) | VAF 35/74 reads (47%) | called by muse, mutect2, varscan2
- KRT6C | c.765T>C p.D255= | Silent (SNP) | VAF 58/413 reads (14%) | called by muse, mutect2, varscan2
- LILRB1 | c.612G>C p.L204= (on ENST00000427581; = p.L168= on NM_006669.6) | Silent (SNP) | VAF 26/166 reads (16%) | called by muse, varscan2
- MCF2 | c.1644C>T p.N548= | Silent (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- MRPL53 | c.12C>A p.A4= | Silent (SNP) | VAF 14/112 reads (13%) | called by muse, mutect2, varscan2
- MYH10 | c.2244A>G p.E748= | Silent (SNP) | VAF 19/104 reads (18%) | called by muse, mutect2, varscan2
- NEK11 | c.1932T>C p.H644= | Silent (SNP) | VAF 52/143 reads (36%) | catalogued as rs751805886; called by muse, mutect2, varscan2
- NR1I2 | c.498C>T p.F166= | Silent (SNP) | VAF 38/324 reads (12%) | called by muse, mutect2, varscan2
- OR2H1 | c.21C>T p.P7= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs1315124795, COSV65810398; called by muse, varscan2
- OR2L8 | c.516C>A p.A172= | Silent (SNP) | VAF 42/177 reads (24%) | called by muse, mutect2, varscan2
- OR56A1 | c.795C>T p.N265= | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as rs750242905, COSV57361753; called by muse, mutect2, varscan2
- P2RY2 | c.729C>T p.S243= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100232653; called by muse, mutect2
- PCDHAC1 | c.2166A>G p.T722= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as rs372120484; called by mutect2, varscan2
- PCLO | c.9264T>C p.V3088= | Silent (SNP) | VAF 27/203 reads (13%) | called by muse, mutect2, varscan2
- PCNX3 | c.3324C>T p.F1108= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as rs532567013; called by muse, mutect2, varscan2
- PDZRN3 | c.2457C>T p.T819= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1276896667; called by mutect2, varscan2
- PDZRN3 | c.1845C>T p.S615= | Silent (SNP) | VAF 29/139 reads (21%) | catalogued as rs780327711, COSV55200754; called by muse, mutect2, varscan2
- PLCB1 | c.963C>T p.P321= | Silent (SNP) | VAF 21/167 reads (13%) | called by muse, mutect2, varscan2
- POFUT1 | c.528A>G p.E176= | Silent (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- RARS1 | c.1728G>C p.R576= | Silent (SNP) | VAF 62/403 reads (15%) | called by muse, mutect2, varscan2
- RBPJ | c.429A>G p.V143= | Silent (SNP) | VAF 23/154 reads (15%) | called by muse, mutect2, varscan2
- SCYL2 | c.2169G>A p.L723= | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- SLC44A1 | c.60G>T p.P20= | Silent (SNP) | VAF 16/82 reads (20%) | called by muse, mutect2, varscan2
- SLC46A1 | c.1125C>A p.I375= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- SLC4A3 | c.615C>T p.S205= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- SLC9A7 | c.783C>A p.A261= | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- SOX3 | c.438C>T p.F146= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs754358326, COSV100983771; called by muse, mutect2, varscan2
- TBX22 | c.21G>A p.A7= | Silent (SNP) | VAF 29/201 reads (14%) | catalogued as COSV64784970, COSV64786267; called by muse, mutect2, varscan2
- TECPR1 | c.51G>A p.T17= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as rs758450212; called by muse, varscan2
- TEX47 | c.81T>A p.R27= | Silent (SNP) | VAF 28/127 reads (22%) | called by muse, mutect2, varscan2
- TM2D3 | c.696C>T p.L232= (on ENST00000333202 / NM_078474.3; = p.L206= on NM_025141.3) | Silent (SNP) | VAF 11/121 reads (9%) | catalogued as rs774904606, COSV60881707; called by muse, mutect2
- TOGARAM1 | c.369G>A p.R123= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV61888572; called by muse, mutect2
- TRH | c.393G>A p.Q131= | Silent (SNP) | VAF 88/238 reads (37%) | catalogued as COSV57015398; called by muse, mutect2, varscan2
- TSPAN10 | c.771G>A p.Q257= (on ENST00000574882 / NM_001290212.1; = p.Q219= on NM_031945.4) | Silent (SNP) | VAF 41/214 reads (19%) | called by muse, mutect2, varscan2
- WDR17 | c.324G>A p.V108= | Silent (SNP) | VAF 40/293 reads (14%) | called by muse, mutect2, varscan2
- ZNF136 | c.1065A>G p.E355= | Silent (SNP) | VAF 22/120 reads (18%) | called by muse, mutect2, varscan2
- ZNF43 | c.1098A>C p.A366= | Silent (SNP) | VAF 62/274 reads (23%) | called by muse, mutect2, varscan2
- ZNF493 | c.1827A>C p.G609= | Silent (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- AC136759.1 | n.563G>C | RNA (SNP) | VAF 38/236 reads (16%) | called by muse, mutect2, varscan2
- ACTR3BP2 | n.977A>T | RNA (SNP) | VAF 19/193 reads (10%) | called by muse, mutect2, varscan2
- ADH5P5 | chr5:23977843 G>T | 5'Flank (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- AP002414.1 | n.123A>G | RNA (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- C2orf72 | c.*23C>A | 3'UTR (SNP) | VAF 30/151 reads (20%) | called by muse, mutect2, varscan2
- COL7A1 | c.*47del | 3'UTR (DEL) | VAF 26/96 reads (27%) | called by mutect2, pindel, varscan2
- DDX60 | c.5039+57G>C | Intron (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- DOK3 | chr5:177503233 G>A | 3'Flank (SNP) | VAF 22/137 reads (16%) | catalogued as rs1382677318; called by muse, mutect2, varscan2
- GIT1 | c.761+13C>G | Intron (SNP) | VAF 26/164 reads (16%) | called by muse, mutect2, varscan2
- OSBPL9 | chr1:51617090 T>C | 5'Flank (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- PCF11 | c.*20T>C | 3'UTR (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- PDZD11 | c.-4C>A | 5'UTR (SNP) | VAF 33/218 reads (15%) | called by muse, mutect2, varscan2
- PRKAG2 | c.1005+42G>T | Intron (SNP) | VAF 30/140 reads (21%) | called by mutect2, varscan2
- PTPRT | chr20:43189742 C>G | 5'Flank (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- RNASET2 | c.446+227G>A | Intron (SNP) | VAF 23/148 reads (16%) | called by muse, mutect2, varscan2
- SCARB2 | chr4:76214301 T>A | 5'Flank (SNP) | VAF 24/170 reads (14%) | called by muse, mutect2, varscan2
- SHKBP1 | c.261-18G>C | Intron (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- SLITRK1 | c.*28A>G | 3'UTR (SNP) | VAF 24/108 reads (22%) | called by mutect2, varscan2
- SNAI2 | c.*24A>T | 3'UTR (SNP) | VAF 28/186 reads (15%) | called by muse, mutect2, varscan2
- STX4 | chr16:31033508 A>T | 5'Flank (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- SULT1A3 | chr16:30206164 C>T | 3'Flank (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- TMC2 | c.1872+65G>A | Intron (SNP) | VAF 37/168 reads (22%) | called by muse, mutect2, varscan2
- TUBB4AP1 | n.507T>A | RNA (SNP) | VAF 23/142 reads (16%) | called by muse, mutect2, varscan2
- UBE3B | c.630+104A>G | Intron (SNP) | VAF 24/156 reads (15%) | called by muse, mutect2
